Somatic mutation profile of tumor specimen ALCH-B43S-TTR1-A (aliquot ALCH-B43S-TTR1-A-1-0-D-A85H-36) from ALCHEMIST case ALCH-B43S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 78.8 years (28,772 days).
Specimen ALCH-B43S-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12fae0c0-beea-4bc2-95d3-4ffa5b800c27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B43S-NB1-A (Blood Derived Normal), aliquot ALCH-B43S-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43e85ddb-28b7-4891-8f11-8594552e824a

The open-access MAF lists 287 somatic variants for this specimen: 176 protein-altering or splice-affecting, 70 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 145, Silent 70, Intron 22, Nonsense Mutation 15, RNA 8, Frame Shift Del 5, Splice Region 5, 5'UTR 5, 3'UTR 4, Frame Shift Ins 3, Splice Site 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 194/473 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- AK5 | c.726C>A p.F242L (on ENST00000354567 / NM_174858.3; = p.F216L on NM_012093.4) | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.944); catalogued as COSV60983718; called by muse, mutect2, varscan2
- ASIC2 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 118/221 reads (53%) | SIFT tolerated (0.36); PolyPhen benign (0.142); catalogued as COSV100726564; called by muse, mutect2, varscan2
- B3GNTL1 | c.505-2A>T p.X169_splice | Splice Site (SNP) | VAF 42/155 reads (27%) | catalogued as COSV57954087; called by muse, mutect2, varscan2
- BNC1 | c.1688C>A p.S563* | Nonsense Mutation (SNP) | VAF 227/496 reads (46%) | catalogued as COSV100597469, COSV100597516; called by muse, mutect2, varscan2
- CADPS2 | c.1227G>T p.W409C | Missense Mutation (SNP) | VAF 93/224 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57389633; called by muse, mutect2, varscan2
- CES2 | c.1147C>G p.P383A | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.097); catalogued as COSV57697465; called by muse, mutect2, varscan2
- CHSY3 | c.2189G>A p.R730Q | Missense Mutation (SNP) | VAF 81/216 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV59285928; called by muse, mutect2, varscan2
- CNTNAP2 | c.786C>A p.H262Q | Missense Mutation (SNP) | VAF 152/445 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.27); catalogued as COSV62155886; called by muse, mutect2, varscan2
- DCHS1 | c.9883G>A p.E3295K | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54995863; called by muse, mutect2, varscan2
- DNAH3 | c.3430G>C p.E1144Q | Missense Mutation (SNP) | VAF 86/251 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.403); catalogued as COSV54501144, COSV54533273; called by muse, mutect2, varscan2
- DNAI2 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 125/209 reads (60%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.912); catalogued as rs755972641, COSV56757330; called by muse, mutect2, varscan2
- FERD3L | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 85/317 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51762358; called by muse, mutect2, varscan2
- FNDC7 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs746928344; called by muse, mutect2, varscan2
- FUS | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.549); catalogued as rs753458243, CM1510998; called by muse, mutect2, varscan2
- GABRG2 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 133/405 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100729873; called by muse, mutect2, varscan2
- GABRG2 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 134/401 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62723536; called by muse, mutect2, varscan2
- GAPDHS | c.644C>A p.S215Y | Missense Mutation (SNP) | VAF 98/113 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as rs761240119; called by muse, mutect2, varscan2
- GARNL3 | c.466A>G p.S156G | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs774224753; called by muse, mutect2, varscan2
- GDF10 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 121/297 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.448); catalogued as rs782809728; called by muse, mutect2, varscan2
- GDF9 | c.209C>G p.S70C | Missense Mutation (SNP) | VAF 85/208 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs933014086, COSV51525851, COSV99737546; called by muse, mutect2, varscan2
- GDF9 | c.97C>G p.Q33E | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.052); catalogued as rs765564948; called by muse, mutect2, varscan2
- GPATCH2L | c.1247G>T p.R416L | Missense Mutation (SNP) | VAF 152/403 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55052533; called by muse, mutect2, varscan2
- HGF | c.1939C>T p.R647* | Nonsense Mutation (SNP) | VAF 131/448 reads (29%) | catalogued as rs545249104, COSV55956856; called by muse, mutect2, varscan2
- HMCN1 | c.13885G>A p.A4629T | Missense Mutation (SNP) | VAF 92/702 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as rs774423771; called by muse, mutect2, varscan2
- HOXD11 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 122/294 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50912605; called by muse, mutect2, varscan2
- HTATIP2 | c.373A>T p.K125* | Nonsense Mutation (SNP) | VAF 78/169 reads (46%) | catalogued as rs754157913; called by muse, mutect2, varscan2
- HTR1A | c.1189C>A p.P397T | Missense Mutation (SNP) | VAF 100/242 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60502922; called by muse, mutect2, varscan2
- HTR5A | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 76/354 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.098); catalogued as rs563677103, COSV55286105; called by muse, mutect2, varscan2
- IQSEC3 | c.1361G>A p.R454Q (on ENST00000538872 / NM_001170738.2; = p.R151Q on NM_015232.1) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs782492131; called by muse, mutect2, varscan2
- KEAP1 | c.756G>T p.W252C | Missense Mutation (SNP) | VAF 143/187 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50274462, COSV50300442; called by muse, mutect2, varscan2
- KEAP1 | c.755G>T p.W252L | Missense Mutation (SNP) | VAF 144/188 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV50344880; called by muse, mutect2, varscan2
- KMT2A | c.7340del p.L2447Wfs*6 | Frame Shift Del (DEL) | VAF 27/83 reads (33%) | catalogued as COSV63291880; called by mutect2, pindel, varscan2
- LIPC | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 204/618 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV54428006; called by muse, mutect2, varscan2
- MAPK15 | c.1514C>G p.S505C | Missense Mutation (SNP) | VAF 111/300 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as rs1330909148, COSV62027967; called by muse, mutect2, varscan2
- MPI | c.62T>A p.M21K | Missense Mutation (SNP) | VAF 144/442 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs778966484; called by muse, mutect2, varscan2
- MYO5A | c.2546G>A p.R849Q | Missense Mutation (SNP) | VAF 166/402 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs754654495, COSV62564531; called by muse, mutect2, varscan2
- NAA30 | c.681C>G p.I227M | Missense Mutation (SNP) | VAF 68/197 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV100035765; called by muse, mutect2, varscan2
- NAALAD2 | c.1550G>A p.R517K | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.617); catalogued as COSV58959701; called by muse, mutect2, varscan2
- NHS | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 129/153 reads (84%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1156244479; called by muse, mutect2, varscan2
- NPAS2 | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 114/298 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs564795063, COSV59561142; called by muse, mutect2, varscan2
- OBSCN | c.8998G>T p.V3000L | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as rs765338702; called by muse, mutect2
- OR11H1 | c.751G>C p.V251L | Missense Mutation (SNP) | VAF 87/371 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV99421867; called by muse, mutect2, varscan2
- OR5M11 | c.866A>G p.Y289C | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV101602067; called by muse, mutect2, varscan2
- ORC4 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 99/326 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as rs752102540; called by muse, mutect2, varscan2
- OSR2 | c.41C>A p.P14Q | Missense Mutation (SNP) | VAF 155/511 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs764701063, COSV52556072; called by muse, mutect2, varscan2
- OVCH1 | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 181/382 reads (47%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.444); catalogued as COSV99758846; called by muse, mutect2, varscan2
- PAFAH1B1 | c.1160-3C>G | Splice Region (SNP) | VAF 40/194 reads (21%) | catalogued as COSV68210193; called by muse, varscan2
- PCDHB8 | c.522C>A p.S174R | Missense Mutation (SNP) | VAF 122/686 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV50809322; called by muse, mutect2, varscan2
- RBM10 | c.2282G>C p.C761S | Missense Mutation (SNP) | VAF 148/160 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61312475; called by muse, mutect2, varscan2
- RCAN1 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV58249993, COSV58250681; called by muse, mutect2, varscan2
- RIIAD1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as COSV51884950, COSV51885528; called by muse, mutect2, varscan2
- RPGRIP1 | c.3461C>T p.S1154L | Missense Mutation (SNP) | VAF 66/197 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs188312873; called by muse, mutect2, varscan2
- SEMA4F | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 104/265 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140925977, COSV60282287; called by muse, mutect2, varscan2
- SHANK2 | c.2534G>A p.R845Q | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.49); catalogued as rs782015001, COSV53585885; ClinVar: uncertain significance; called by mutect2, varscan2
- SIRT1 | c.1609G>A p.D537N | Missense Mutation (SNP) | VAF 83/289 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs1308551562; called by muse, mutect2, varscan2
- SLC17A6 | c.232G>T p.G78C | Missense Mutation (SNP) | VAF 176/544 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.053); catalogued as COSV54134347; called by muse, mutect2, varscan2
- SLC2A13 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753076022, COSV55121511; called by muse, mutect2, varscan2
- SRGAP3 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 143/366 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV64531169, COSV64542042; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.228C>G p.D76E | Missense Mutation (SNP) | VAF 26/95 reads (27%) | PolyPhen benign (0.103); catalogued as COSV60328642; called by muse, mutect2, varscan2
- STK11IP | c.3229C>T p.R1077W | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776082847, COSV55246261; called by muse, mutect2, varscan2
- TAF3 | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 48/122 reads (39%) | catalogued as COSV60203131; called by muse, mutect2, varscan2
- TCF7L2 | c.1210C>T p.R404W (on ENST00000355995 / NM_001367943.1; = p.R381W on NM_030756.5) | Missense Mutation (SNP) | VAF 49/238 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99526865; called by muse, mutect2, varscan2
- TG | c.4552G>A p.E1518K | Missense Mutation (SNP) | VAF 343/638 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs200687678, COSV99602604; called by muse, mutect2, varscan2
- TGFBI | c.1437C>G p.I479M | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.977); catalogued as COSV100526213; called by muse, mutect2, varscan2
- THSD7A | c.3064G>A p.G1022S | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70262451; called by muse, mutect2, varscan2
- TLR4 | c.800G>T p.G267V (on ENST00000355622 / NM_138554.5; = p.G227V on NM_003266.4) | Missense Mutation (SNP) | VAF 62/458 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV62924103; called by muse, mutect2, varscan2
- TMEM132B | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 89/253 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54757496, COSV54762045; called by muse, mutect2, varscan2
- TMEM132E | c.2680C>T p.H894Y (on ENST00000321639; = p.H984Y on NM_001304438.2) | Missense Mutation (SNP) | VAF 72/128 reads (56%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs1432623790; called by muse, mutect2, varscan2
- UGT1A7 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 102/381 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs761343712, COSV60839632; called by muse, mutect2, varscan2
- ULK4 | c.3120+1G>T p.X1040_splice | Splice Site (SNP) | VAF 30/99 reads (30%) | catalogued as COSV100093718; called by muse, mutect2, varscan2
- YY1AP1 | c.581C>T p.P194L (on ENST00000295566 / NM_139118.2; = p.P117L on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/386 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs771511749; called by muse, mutect2, varscan2
- ZDHHC12 | c.532G>T p.G178W | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs779856643, COSV52578358; called by muse, mutect2, varscan2
- ZSCAN5A | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 159/192 reads (83%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs761986359; called by muse, mutect2, varscan2
- ZSCAN5C | c.933G>C p.E311D | Missense Mutation (SNP) | VAF 75/388 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs771567380; called by muse, mutect2, varscan2
- AAR2 | c.782G>C p.C261S | Missense Mutation (SNP) | VAF 105/272 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABCA1 | c.3497G>T p.G1166V | Missense Mutation (SNP) | VAF 389/662 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ADAMTSL1 | c.2977C>T p.Q993* | Nonsense Mutation (SNP) | VAF 75/100 reads (75%) | called by muse, mutect2, varscan2
- ADGRB3 | c.2775T>A p.N925K | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRG4 | c.2902G>A p.A968T | Missense Mutation (SNP) | VAF 46/62 reads (74%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD36B | c.411A>T p.K137N | Missense Mutation (SNP) | VAF 70/208 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.061); called by muse, mutect2
- ATG14 | c.1066C>G p.L356V | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP2B3 | c.1786C>G p.L596V | Missense Mutation (SNP) | VAF 76/83 reads (92%) | SIFT tolerated (0.63); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ATP8A1 | c.1504C>G p.Q502E | Missense Mutation (SNP) | VAF 57/376 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- AVL9 | c.1744T>C p.S582P | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BAIAP3 | c.2723C>G p.S908W | Missense Mutation (SNP) | VAF 92/193 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- BCORL1 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 95/112 reads (85%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C2orf68 | c.108-8C>A | Splice Region (SNP) | VAF 91/218 reads (42%) | called by muse, mutect2, varscan2
- CARS2 | c.73G>T p.G25W | Missense Mutation (SNP) | VAF 128/172 reads (74%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH8 | c.907C>A p.Q303K | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDK5R1 | c.156G>T p.W52C | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEP170 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 95/349 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CEP78 | c.1006A>C p.K336Q | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CFAP91 | c.2086G>T p.E696* | Nonsense Mutation (SNP) | VAF 79/254 reads (31%) | called by muse, mutect2, varscan2
- DAG1 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 186/389 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCSTAMP | c.438G>T p.E146D | Missense Mutation (SNP) | VAF 159/311 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- DENND4C | c.2764G>T p.G922W | Missense Mutation (SNP) | VAF 75/108 reads (69%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DIPK1C | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- DOT1L | c.2039del p.G680Afs*25 | Frame Shift Del (DEL) | VAF 153/234 reads (65%) | called by mutect2, pindel, varscan2
- ERAP1 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 96/329 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EVI5L | c.2048C>G p.S683W | Missense Mutation (SNP) | VAF 96/117 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- F2RL2 | c.880C>G p.H294D | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM205A | c.1005G>T p.Q335H | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- FAT3 | c.4181G>T p.W1394L | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GBP3 | c.190+7G>A | Splice Region (SNP) | VAF 52/265 reads (20%) | called by muse, mutect2, varscan2
- GBP5 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GIMAP7 | c.418del p.Q140Rfs*7 | Frame Shift Del (DEL) | VAF 44/198 reads (22%) | called by mutect2, pindel, varscan2
- GOLGA7 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 58/72 reads (81%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, varscan2
- GOLGA7 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 70/90 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, varscan2
- GPRIN1 | c.2824C>G p.L942V | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GSPT2 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- HEXIM1 | c.883G>C p.E295Q | Missense Mutation (SNP) | VAF 147/263 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- IFFO2 | c.842C>G p.T281R | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- IFT122 | c.3077A>G p.Y1026C (on ENST00000348417 / NM_052989.3; = p.Y967C on NM_018262.4) | Missense Mutation (SNP) | VAF 202/640 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- ING4 | c.447C>G p.N149K (on ENST00000396807 / NM_001127582.2; = p.N148K on NM_016162.4) | Missense Mutation (SNP) | VAF 98/194 reads (51%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KATNIP | c.1733C>A p.T578K | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.164); called by muse, mutect2
- KATNIP | c.1735G>T p.A579S | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.572); called by muse, mutect2
- KCNAB1 | c.572G>C p.G191A (on ENST00000490337 / NM_172160.3; = p.G180A on NM_003471.3) | Missense Mutation (SNP) | VAF 102/259 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- KCNH5 | c.2021T>G p.I674S | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- KRBA2 | c.1107G>C p.K369N | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- KRTAP10-11 | c.269G>A p.C90Y | Missense Mutation (SNP) | VAF 111/457 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- LARP1 | c.2462G>T p.R821I (on ENST00000518297 / NM_033551.3; = p.R744I on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- LDB2 | c.346A>T p.I116F | Missense Mutation (SNP) | VAF 49/275 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- LOXHD1 | c.3799C>A p.L1267I | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- LTK | c.2060T>A p.V687D | Missense Mutation (SNP) | VAF 72/147 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MCC | c.978dup p.A327Cfs*2 | Frame Shift Ins (INS) | VAF 63/206 reads (31%) | called by mutect2, pindel, varscan2
- MEOX1 | c.570T>A p.F190L | Missense Mutation (SNP) | VAF 77/151 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MPI | c.63G>T p.M21I | Missense Mutation (SNP) | VAF 145/444 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- MROH1 | c.4227G>A p.M1409I | Missense Mutation (SNP) | VAF 100/688 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MROH2B | c.4032A>C p.L1344F | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- MUC5AC | c.14237C>A p.A4746D | Missense Mutation (SNP) | VAF 110/202 reads (54%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- MUC5AC | c.15009C>T p.I5003= | Splice Region (SNP) | VAF 55/82 reads (67%) | called by muse, mutect2, varscan2
- NCAM1 | c.1195A>G p.N399D (on ENST00000316851 / NM_181351.5; = p.N389D on NM_000615.7) | Missense Mutation (SNP) | VAF 95/172 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- NIN | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 45/127 reads (35%) | called by muse, mutect2, varscan2
- NRXN1 | c.2777C>T p.S926F | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- OBSCN | c.3940C>T p.Q1314* | Nonsense Mutation (SNP) | VAF 60/428 reads (14%) | called by muse, mutect2
- OLFML2A | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 70/380 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- OR14K1 | c.716G>T p.C239F | Missense Mutation (SNP) | VAF 79/275 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- OR56B4 | c.414C>A p.Y138* | Nonsense Mutation (SNP) | VAF 26/111 reads (23%) | called by muse, mutect2, varscan2
- OR6K2 | c.443del p.C148Lfs*49 | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | called by mutect2, pindel, varscan2
- PCDH17 | c.899C>T p.T300I | Missense Mutation (SNP) | VAF 76/424 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- PCDHB15 | c.2089G>A p.V697M | Missense Mutation (SNP) | VAF 212/499 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PKD2L1 | c.1000dup p.W334Lfs*23 | Frame Shift Ins (INS) | VAF 88/283 reads (31%) | called by mutect2, pindel, varscan2
- POC1B-GALNT4 | c.1412T>C p.L471P | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PPP1R2C | c.453C>G p.I151M | Missense Mutation (SNP) | VAF 95/265 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- PTK2 | c.1190A>G p.Y397C | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTK6 | c.22C>T p.H8Y | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RBBP7 | c.791C>G p.P264R | Missense Mutation (SNP) | VAF 144/176 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RGL1 | c.1741C>T p.Q581* (on ENST00000360851 / NM_001297672.2; = p.Q616* on NM_015149.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 60/168 reads (36%) | called by muse, mutect2, varscan2
- SCUBE2 | c.290G>C p.G97A | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEMA6D | c.1589A>G p.D530G | Missense Mutation (SNP) | VAF 31/261 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC39A9 | c.473-4A>G | Splice Region (SNP) | VAF 65/163 reads (40%) | called by muse, mutect2, varscan2
- SMC3 | c.679A>G p.I227V | Missense Mutation (SNP) | VAF 96/283 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- SRPX | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 58/75 reads (77%) | called by muse, mutect2, varscan2
- STARD9 | c.3278C>G p.S1093* | Nonsense Mutation (SNP) | VAF 40/145 reads (28%) | called by muse, mutect2, varscan2
- STK11 | c.899T>A p.I300N | Missense Mutation (SNP) | VAF 189/214 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SYNJ1 | c.2951G>A p.G984E | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- TEAD3 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 153/324 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- TEKT5 | c.697C>G p.Q233E | Missense Mutation (SNP) | VAF 57/185 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- TERF2 | c.1280C>T p.S427L | Missense Mutation (SNP) | VAF 124/223 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLR4 | c.799G>T p.G267* (on ENST00000355622 / NM_138554.5; = p.G227* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 60/450 reads (13%) | called by muse, varscan2
- TMEM132E | c.196C>G p.P66A | Missense Mutation (SNP) | VAF 181/333 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNS2 | c.1849G>A p.E617K (on ENST00000314250 / NM_170754.4; = p.E627K on NM_015319.2) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- TRIM15 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 157/403 reads (39%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTC3 | c.746T>A p.I249K | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- UBE3B | c.2080G>T p.G694C | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- UBXN7 | c.1294C>T p.Q432* | Nonsense Mutation (SNP) | VAF 77/219 reads (35%) | called by muse, mutect2, varscan2
- UNK | c.1043C>G p.S348C | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- WDR81 | c.101T>C p.V34A | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0.03); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- YIPF1 | c.769G>T p.V257F | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- YTHDC1 | c.1352G>T p.R451L (on ENST00000344157 / NM_001031732.4; = p.R433L on NM_133370.4) | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- ZFP36 | c.963dup p.L322Tfs*11 (on ENST00000594442; = p.L316Tfs*11 on NM_003407.5) | Frame Shift Ins (INS) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- ZNF337 | c.1876C>T p.Q626* | Nonsense Mutation (SNP) | VAF 71/174 reads (41%) | called by muse, mutect2, varscan2
- ZNF593 | c.287_288del p.P96Lfs*30 | Frame Shift Del (DEL) | VAF 125/318 reads (39%) | called by mutect2, pindel, varscan2
- ZNF717 | c.1904G>T p.S635I | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ZNF780A | c.1832A>G p.K611R | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ACSBG2 | c.1146C>A p.V382= | Silent (SNP) | VAF 104/150 reads (69%) | called by muse, mutect2, varscan2
- ADAMTS14 | c.324C>T p.F108= | Silent (SNP) | VAF 185/454 reads (41%) | called by muse, mutect2, varscan2
- ADGRG7 | c.84C>T p.G28= | Silent (SNP) | VAF 42/285 reads (15%) | catalogued as COSV56294997; called by muse, mutect2, varscan2
- ADGRL3 | c.4452C>A p.P1484= (on ENST00000506720 / NM_001322402.2; = p.P1373= on NM_015236.6) | Silent (SNP) | VAF 68/489 reads (14%) | catalogued as rs548907641; called by muse, mutect2, varscan2
- AHNAK2 | c.978C>T p.L326= | Silent (SNP) | VAF 14/35 reads (40%) | called by muse, varscan2
- AQR | c.3801G>A p.Q1267= | Silent (SNP) | VAF 139/313 reads (44%) | catalogued as COSV99334191; called by muse, mutect2, varscan2
- ARHGEF33 | c.111C>T p.F37= | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as COSV67257818; called by muse, mutect2, varscan2
- ATP10D | c.3769C>T p.L1257= | Silent (SNP) | VAF 47/94 reads (50%) | called by muse, mutect2
- BRIX1 | c.189C>T p.L63= | Silent (SNP) | VAF 34/139 reads (24%) | catalogued as rs1159505314; called by muse, mutect2, varscan2
- CACNA1H | c.6474G>C p.A2158= | Silent (SNP) | VAF 40/72 reads (56%) | catalogued as COSV52352998; called by muse, mutect2, varscan2
- CFLAR | c.1224G>T p.A408= | Silent (SNP) | VAF 125/294 reads (43%) | called by muse, mutect2, varscan2
- CRAT | c.852C>T p.F284= | Silent (SNP) | VAF 105/147 reads (71%) | called by muse, mutect2, varscan2
- CREB5 | c.834G>T p.P278= (on ENST00000357727 / NM_182898.4; = p.P271= on NM_004904.3) | Silent (SNP) | VAF 229/555 reads (41%) | catalogued as COSV100745528; called by muse, mutect2, varscan2
- DACH1 | c.594G>T p.V198= | Silent (SNP) | VAF 45/94 reads (48%) | called by muse, mutect2, varscan2
- DOCK10 | c.5904C>T p.F1968= | Silent (SNP) | VAF 179/476 reads (38%) | catalogued as rs768117264, COSV51379969; called by muse, mutect2, varscan2
- DTWD2 | c.603A>G p.Q201= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as rs780832774; called by muse, mutect2, varscan2
- E2F7 | c.1608G>T p.L536= | Silent (SNP) | VAF 113/227 reads (50%) | called by muse, mutect2, varscan2
- EDEM1 | c.33G>A p.V11= | Silent (SNP) | VAF 30/76 reads (39%) | called by muse, mutect2, varscan2
- ELP2 | c.1833T>A p.V611= | Silent (SNP) | VAF 45/159 reads (28%) | called by muse, mutect2, varscan2
- ELP5 | c.84G>T p.V28= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as rs1361152328; called by muse, mutect2, varscan2
- EPHB1 | c.1665C>T p.S555= | Silent (SNP) | VAF 109/254 reads (43%) | catalogued as COSV67669164; called by muse, mutect2, varscan2
- GUCY2D | c.1239G>T p.R413= | Silent (SNP) | VAF 195/360 reads (54%) | called by muse, varscan2
- HGS | c.402C>T p.I134= | Silent (SNP) | VAF 44/160 reads (28%) | called by muse, varscan2
- HTR1E | c.417C>T p.A139= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as rs146428063, COSV100541098; called by muse, mutect2, varscan2
- IMPG2 | c.2421G>A p.R807= | Silent (SNP) | VAF 74/229 reads (32%) | catalogued as rs767512719; called by muse, mutect2, varscan2
- IVD | c.738G>C p.L246= (on ENST00000651168; = p.L243= on NM_002225.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 170/510 reads (33%) | called by muse, mutect2, varscan2
- JPH4 | c.1506A>T p.A502= | Silent (SNP) | VAF 18/71 reads (25%) | called by mutect2, varscan2
- KBTBD7 | c.1089G>T p.S363= | Silent (SNP) | VAF 268/443 reads (60%) | catalogued as COSV65266955; called by muse, mutect2, varscan2
- KMT2D | c.10869G>A p.Q3623= | Silent (SNP) | VAF 28/46 reads (61%) | called by muse, varscan2
- KNTC1 | c.5019C>T p.T1673= | Silent (SNP) | VAF 63/265 reads (24%) | catalogued as rs756969253; called by muse, mutect2, varscan2
- LAMA5 | c.4149C>G p.V1383= | Silent (SNP) | VAF 58/129 reads (45%) | called by muse, mutect2, varscan2
- LRP12 | c.1656G>A p.L552= | Silent (SNP) | VAF 70/250 reads (28%) | catalogued as COSV52633651; called by muse, mutect2, varscan2
- LRP1B | c.12183G>A p.L4061= | Silent (SNP) | VAF 84/229 reads (37%) | catalogued as rs772583073, COSV67249150; called by muse, mutect2, varscan2
- MINDY1 | c.1402C>T p.L468= | Silent (SNP) | VAF 85/300 reads (28%) | catalogued as rs774523136; called by muse, mutect2, varscan2
- MTERF3 | c.963G>A p.K321= | Silent (SNP) | VAF 56/261 reads (21%) | called by muse, mutect2, varscan2
- MUC6 | c.1950C>A p.L650= | Silent (SNP) | VAF 57/169 reads (34%) | called by muse, mutect2, varscan2
- MXRA8 | c.1317G>A p.E439= | Silent (SNP) | VAF 58/123 reads (47%) | catalogued as rs1199668878; called by muse, mutect2, varscan2
- NCKAP5 | c.1231C>A p.R411= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs1359961801, COSV58438645; called by muse, mutect2, varscan2
- NDST3 | c.720C>T p.T240= | Silent (SNP) | VAF 74/143 reads (52%) | called by muse, mutect2, varscan2
- NOX3 | c.942C>G p.G314= | Silent (SNP) | VAF 57/76 reads (75%) | called by muse, mutect2, varscan2
- NVL | c.1839G>A p.V613= | Silent (SNP) | VAF 99/473 reads (21%) | called by muse, mutect2, varscan2
- OBSCN | c.9000G>T p.V3000= | Silent (SNP) | VAF 45/210 reads (21%) | called by muse, mutect2
- OR13H1 | c.480C>A p.I160= | Silent (SNP) | VAF 51/67 reads (76%) | called by muse, mutect2, varscan2
- OR5M10 | c.375C>A p.A125= | Silent (SNP) | VAF 56/137 reads (41%) | called by muse, mutect2, varscan2
- PDRG1 | c.132G>C p.L44= | Silent (SNP) | VAF 66/201 reads (33%) | catalogued as COSV52430986, COSV52431920; called by muse, mutect2, varscan2
- PIDD1 | c.519C>T p.L173= | Silent (SNP) | VAF 67/117 reads (57%) | called by muse, mutect2, varscan2
- PRKDC | c.7527A>T p.G2509= | Silent (SNP) | VAF 61/228 reads (27%) | called by muse, mutect2, varscan2
- PTCHD4 | c.1758G>A p.Q586= | Silent (SNP) | VAF 88/179 reads (49%) | catalogued as rs764172058, COSV99045023; called by muse, mutect2, varscan2
- PTK7 | c.534C>T p.V178= | Silent (SNP) | VAF 61/190 reads (32%) | catalogued as rs760032225; called by muse, mutect2, varscan2
- PWP1 | c.1227C>T p.Y409= | Silent (SNP) | VAF 78/180 reads (43%) | catalogued as rs367798858; called by muse, mutect2, varscan2
- RGL1 | c.1905G>T p.S635= (on ENST00000360851 / NM_001297672.2; = p.S670= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 150/591 reads (25%) | catalogued as rs371789837; called by muse, mutect2, varscan2
- RNPEPL1 | c.1308G>A p.L436= | Silent (SNP) | VAF 75/166 reads (45%) | catalogued as COSV54372940; called by muse, mutect2, varscan2
- SESN1 | c.205C>T p.L69= | Silent (SNP) | VAF 94/148 reads (64%) | catalogued as rs745513653; called by muse, mutect2, varscan2
- SETX | c.6585C>T p.L2195= | Silent (SNP) | VAF 193/343 reads (56%) | called by muse, mutect2, varscan2
- SH3TC1 | c.3450G>A p.A1150= | Silent (SNP) | VAF 47/210 reads (22%) | catalogued as rs1055955017, COSV55280857; called by muse, mutect2, varscan2
- SOCS6 | c.219G>A p.L73= | Silent (SNP) | VAF 57/325 reads (18%) | catalogued as COSV67546240; called by muse, mutect2, varscan2
- SPCS1 | c.126C>G p.L42= | Silent (SNP) | VAF 117/274 reads (43%) | called by muse, mutect2, varscan2
- SPOCK1 | c.745C>T p.L249= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as rs1018868939; called by muse, mutect2, varscan2
- TC2N | c.975A>G p.S325= | Silent (SNP) | VAF 103/280 reads (37%) | catalogued as rs377422447; called by muse, mutect2, varscan2
- TIMM44 | c.360G>A p.K120= | Silent (SNP) | VAF 249/845 reads (29%) | called by muse, mutect2, varscan2
- TMEM272 | c.186C>T p.I62= | Silent (SNP) | VAF 30/189 reads (16%) | catalogued as rs900017169; called by muse, mutect2, varscan2
- TOGARAM2 | c.963G>T p.T321= | Silent (SNP) | VAF 144/341 reads (42%) | called by muse, mutect2, varscan2
- TOX2 | c.276G>T p.L92= (on ENST00000358131 / NM_001098798.2; = p.L41= on NM_032883.3) | Silent (SNP) | VAF 128/307 reads (42%) | called by muse, mutect2, varscan2
- TRAF2 | c.1278C>T p.F426= | Silent (SNP) | VAF 80/110 reads (73%) | called by muse, mutect2, varscan2
- UNC80 | c.6912G>T p.L2304= | Silent (SNP) | VAF 94/345 reads (27%) | called by muse, mutect2, varscan2
- VPS13C | c.5994C>T p.C1998= (on ENST00000644861 / NM_020821.3; = p.C1955= on NM_017684.5) | Silent (SNP) | VAF 43/405 reads (11%) | catalogued as rs767911166; called by muse, mutect2, varscan2
- WNT4 | c.123G>A p.E41= | Silent (SNP) | VAF 124/451 reads (27%) | catalogued as rs746248932; called by muse, mutect2, varscan2
- YEATS2 | c.2622A>G p.K874= | Silent (SNP) | VAF 77/179 reads (43%) | called by muse, mutect2, varscan2
- ZNF493 | c.243T>A p.S81= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV62749460; called by muse, mutect2, varscan2
- ZNF729 | c.2205T>A p.T735= | Silent (SNP) | VAF 112/185 reads (61%) | catalogued as COSV100675533; called by muse, mutect2, varscan2
- ABCG5 | c.502-275G>C | Intron (SNP) | VAF 33/65 reads (51%) | catalogued as rs1250946261; called by muse, mutect2, varscan2
- AC093791.1 | n.365C>A | RNA (SNP) | VAF 33/204 reads (16%) | called by muse, mutect2, varscan2
- APTX | c.133+167C>G | Intron (SNP) | VAF 26/172 reads (15%) | catalogued as rs754928641; called by muse, mutect2, varscan2
- C2orf68 | c.226+26C>G | Intron (SNP) | VAF 51/141 reads (36%) | called by muse, mutect2, varscan2
- CCDC116 | c.-23C>G | 5'UTR (SNP) | VAF 111/304 reads (37%) | called by muse, mutect2, varscan2
- CHIT1 | c.*535T>A | 3'UTR (SNP) | VAF 79/292 reads (27%) | called by muse, mutect2, varscan2
- CLK2P1 | n.918A>G | RNA (SNP) | VAF 123/322 reads (38%) | called by muse, mutect2, varscan2
- CRB1 | c.4005+28C>T | Intron (SNP) | VAF 89/375 reads (24%) | catalogued as COSV100958055; called by muse, mutect2, varscan2
- DCHS2 | n.7823C>T | RNA (SNP) | VAF 33/212 reads (16%) | catalogued as rs761139903; called by muse, mutect2, varscan2
- DZANK1 | c.379-89A>T | Intron (SNP) | VAF 99/298 reads (33%) | called by muse, mutect2, varscan2
- EPDR1 | c.-23C>T | 5'UTR (SNP) | VAF 57/168 reads (34%) | catalogued as COSV52260837; called by muse, mutect2, varscan2
- FBXW10 | c.871+21G>A | Intron (SNP) | VAF 37/139 reads (27%) | called by muse, mutect2, varscan2
- FER1L4 | n.2617G>A | RNA (SNP) | VAF 63/114 reads (55%) | called by muse, mutect2, varscan2
- FLI1 | c.385+79C>G | Intron (SNP) | VAF 36/61 reads (59%) | catalogued as rs1192376050; called by muse, mutect2, varscan2
- FOXRED1 | c.85+65C>A | Intron (SNP) | VAF 54/211 reads (26%) | called by muse, mutect2, varscan2
- GNRHR | c.*29A>C | 3'UTR (SNP) | VAF 45/82 reads (55%) | called by muse, mutect2, varscan2
- GPS1 | c.33+368C>G | Intron (SNP) | VAF 124/258 reads (48%) | called by muse, mutect2, varscan2
- GVINP1 | n.1983T>A | RNA (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- ISCU | c.418+415G>C | Intron (SNP) | VAF 56/193 reads (29%) | called by muse, mutect2, varscan2
- ISOC2 | c.349-31G>A | Intron (SNP) | VAF 139/158 reads (88%) | catalogued as rs376381485; called by muse, mutect2, varscan2
- KAT6A | c.1483-1807G>A | Intron (SNP) | VAF 170/252 reads (67%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.162A>C | RNA (SNP) | VAF 64/360 reads (18%) | called by muse, mutect2, varscan2
- NDRG2 | c.408-148C>T | Intron (SNP) | VAF 57/137 reads (42%) | called by muse, mutect2, varscan2
- NDUFA2 | c.101+34G>A | Intron (SNP) | VAF 105/243 reads (43%) | called by muse, mutect2, varscan2
- NECTIN3-AS1 | n.823C>G | RNA (SNP) | VAF 125/368 reads (34%) | called by muse, mutect2, varscan2
- NEURL1B | c.-41G>A | 5'UTR (SNP) | VAF 76/154 reads (49%) | called by muse, mutect2, varscan2
- OR6W1P | n.806A>G | RNA (SNP) | VAF 64/177 reads (36%) | called by muse, mutect2, varscan2
- PABPN1 | c.352-37C>A | Intron (SNP) | VAF 59/131 reads (45%) | called by muse, mutect2, varscan2
- PMS2 | chr7:6009066 G>A | 5'Flank (SNP) | VAF 98/200 reads (49%) | called by muse, mutect2, varscan2
- PNKD | c.236+1118C>T | Intron (SNP) | VAF 98/311 reads (32%) | catalogued as rs199646553; called by muse, mutect2, varscan2
- POLI | c.-39G>A | 5'UTR (SNP) | VAF 33/63 reads (52%) | called by muse, mutect2, varscan2
- PPP2R5C | c.630-276G>A | Intron (SNP) | VAF 42/86 reads (49%) | called by muse, mutect2, varscan2
- PTPDC1 | c.83-545T>A | Intron (SNP) | VAF 22/153 reads (14%) | called by muse, mutect2, varscan2
- PTPRM | c.-51C>T | 5'UTR (SNP) | VAF 10/32 reads (31%) | catalogued as rs774947124, COSV100160967; called by muse, mutect2
- RIPPLY3 | c.*64G>T | 3'UTR (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- SPAG16 | c.184-179A>G | Intron (SNP) | VAF 34/119 reads (29%) | called by muse, mutect2
- TNFRSF17 | c.278-509C>T | Intron (SNP) | VAF 5/31 reads (16%) | catalogued as rs137936771; called by muse, mutect2, varscan2
- TP53AIP1 | c.141+154del | Intron (DEL) | VAF 4/28 reads (14%) | catalogued as rs1216454466; called by mutect2, pindel
- TTC19 | c.*913C>T | 3'UTR (SNP) | VAF 41/243 reads (17%) | called by muse, mutect2, varscan2
- UBAP2L | c.2902+1440G>T | Intron (SNP) | VAF 94/350 reads (27%) | called by muse, mutect2, varscan2
- ZNF57 | chr19:2896948 G>A | 5'Flank (SNP) | VAF 88/130 reads (68%) | catalogued as rs772359190; called by muse, mutect2
